Somatic mutation profile of tumor specimen TCGA-CC-A7IG-01A (aliquot TCGA-CC-A7IG-01A-11D-A33K-10) from TCGA case TCGA-CC-A7IG, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 47.8 years (17,453 days).
Specimen TCGA-CC-A7IG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3adc6d27-9d97-41cf-8c32-6080e879dc3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A7IG-10A (Blood Derived Normal), aliquot TCGA-CC-A7IG-10A-01D-A33K-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f327436-a96e-4d2d-915b-38bd224a9560

The open-access MAF lists 150 somatic variants for this specimen: 118 protein-altering or splice-affecting, 31 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 31, Nonsense Mutation 6, Splice Region 3, Frame Shift Del 3, Frame Shift Ins 1, Splice Site 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNGA3 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs763041373, CM051026, COSV55626790; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 58/82 reads (71%) | catalogued as rs786201592, COSV52735606, COSV52751148, COSV52783951; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSBG2 | c.252C>G p.N84K | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV53126817; called by muse, mutect2, varscan2
- ADAMTS7 | c.3778C>A p.L1260M | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.467); catalogued as COSV66308866; called by muse, mutect2, varscan2
- AFG1L | c.162G>T p.E54D | Missense Mutation (SNP) | VAF 68/79 reads (86%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV64557279; called by muse, mutect2, varscan2
- ANO1 | c.1318C>T p.L440F | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60287806; called by muse, mutect2, varscan2
- ARHGEF5 | c.32C>G p.S11C | Missense Mutation (SNP) | VAF 62/538 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs1319134785, COSV99283079; called by muse, mutect2, varscan2
- ARL13B | c.487G>A p.E163K (on ENST00000394222 / NM_001174150.2; = p.E56K on NM_144996.4) | Missense Mutation (SNP) | VAF 36/350 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.627); catalogued as COSV57400444; called by muse, mutect2
- ASNS | c.940C>G p.L314V | Missense Mutation (SNP) | VAF 81/284 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV51554922; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3619C>G p.Q1207E | Missense Mutation (SNP) | VAF 116/622 reads (19%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.945); catalogued as COSV63244736, COSV63246582; called by muse, mutect2, varscan2
- C18orf25 | c.466A>T p.K156* | Nonsense Mutation (SNP) | VAF 52/132 reads (39%) | catalogued as COSV56368185; called by muse, mutect2, varscan2
- C2CD2L | c.440A>G p.E147G | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV60884568; called by muse, mutect2, varscan2
- C2CD2L | c.1931G>T p.G644V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60884403, COSV60884577; called by muse, mutect2, varscan2
- CCDC80 | c.2426G>A p.G809D | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1306438190, COSV52819038; called by muse, mutect2, varscan2
- CCR6 | c.113T>C p.L38S | Missense Mutation (SNP) | VAF 45/62 reads (73%) | SIFT tolerated (0.25); PolyPhen benign (0.119); catalogued as COSV59475857; called by muse, mutect2, varscan2
- CDCP1 | c.401G>T p.S134I | Missense Mutation (SNP) | VAF 89/150 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.116); catalogued as COSV56105064, COSV56107223; called by muse, mutect2, varscan2
- CELSR1 | c.2230A>G p.I744V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.268); catalogued as COSV53096610; called by muse, mutect2, varscan2
- CHPF | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as rs142415191, COSV60534550, COSV60535493; called by muse, mutect2, varscan2
- CHRNA9 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 128/238 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59575490; called by muse, mutect2, varscan2
- CPA6 | c.1157C>A p.A386D | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52738661; called by muse, mutect2, varscan2
- CRHR1 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV53283598; called by muse, mutect2, varscan2
- CSMD1 | c.4049G>A p.S1350N (on ENST00000520002; = p.S1349N on NM_033225.6) | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV59361982; called by muse, mutect2, varscan2
- DDIAS | c.1973A>G p.N658S | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs369733646; called by muse, mutect2, varscan2
- DNAH10 | c.7430A>T p.Y2477F (on ENST00000409039; = p.Y2416F on NM_207437.3) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.822); catalogued as COSV68998876; called by muse, varscan2
- DOCK2 | c.66C>A p.S22R | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.047); catalogued as COSV56978153, COSV99916526; called by muse, varscan2
- DPYSL5 | c.776C>G p.A259G | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV56514967; called by muse, mutect2, varscan2
- EPSTI1 | c.257A>T p.Q86L | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV58047771; called by muse, mutect2, varscan2
- ERBIN | c.3952G>T p.A1318S (on ENST00000284037 / NM_001253697.2; = p.A1277S on NM_018695.4) | Missense Mutation (SNP) | VAF 144/298 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV52323715; called by muse, mutect2, varscan2
- F13A1 | c.717C>A p.C239* | Nonsense Mutation (SNP) | VAF 25/59 reads (42%) | catalogued as COSV53564389; called by muse, mutect2, varscan2
- FAR1 | c.1435T>C p.W479R | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV61385984; called by muse, mutect2, varscan2
- FAT3 | c.10613G>A p.R3538H | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs755030491, COSV53133261; called by muse, mutect2, varscan2
- FCAR | c.308G>A p.R103K | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV62028087; called by muse, mutect2, varscan2
- FEZ2 | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59907020; called by muse, mutect2
- FREM2 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 89/119 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV54846868, COSV54849989; called by muse, mutect2, varscan2
- GUCY1A2 | c.987C>G p.F329L | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56496413; called by muse, mutect2, varscan2
- HECW1 | c.1859C>A p.P620H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.078); catalogued as COSV67829609; called by muse, mutect2, varscan2
- HERC2 | c.12464C>T p.A4155V | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55341905; called by muse, mutect2, varscan2
- HHIP | c.935T>C p.I312T | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV56842765; called by muse, mutect2
- HID1 | c.346G>T p.G116C | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV59352072; called by muse, mutect2, varscan2
- HOOK1 | c.1245A>G p.R415= | Splice Region (SNP) | VAF 158/195 reads (81%) | catalogued as COSV64620338; called by muse, mutect2, varscan2
- HPS6 | c.2109G>T p.E703D | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54626447; called by muse, mutect2, varscan2
- IER2 | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV52848691; called by muse, mutect2, varscan2
- IGHV3-38 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs369602723; called by muse, mutect2, varscan2
- INTS4 | c.326G>A p.C109Y | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.365); catalogued as COSV71090786; called by muse, mutect2, varscan2
- ITGA2B | c.2341C>G p.L781V | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as rs542591743, COSV52234227; called by muse, mutect2, varscan2
- JAK3 | c.2959G>A p.G987S | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.41); catalogued as COSV71686998, COSV71688035; called by muse, mutect2, varscan2
- KDM3B | c.5065C>T p.H1689Y | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV58691791; called by muse, mutect2
- KIAA0753 | c.1723C>G p.L575V | Missense Mutation (SNP) | VAF 45/61 reads (74%) | SIFT tolerated (0.24); PolyPhen benign (0.059); catalogued as rs765589499, COSV63818396; called by muse, mutect2, varscan2
- KIF7 | c.1673C>A p.S558Y | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV67998777; called by muse, mutect2, varscan2
- KLF15 | c.1208A>T p.H403L | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56180817; called by muse, mutect2, varscan2
- KNTC1 | c.3614A>T p.E1205V | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV61082834; called by muse, mutect2, varscan2
- KPRP | c.1352G>T p.R451L | Missense Mutation (SNP) | VAF 45/48 reads (94%) | SIFT tolerated (0.15); PolyPhen benign (0.357); catalogued as rs755668740, COSV64222581; called by muse, mutect2, varscan2
- LAMA3 | c.3536A>T p.E1179V | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.786); catalogued as COSV58075752; called by muse, varscan2
- LGI4 | c.292G>T p.G98C | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59534534; called by muse, mutect2, varscan2
- LMLN | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV54564626; called by muse, mutect2, varscan2
- LYPD3 | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV54989406; called by muse, mutect2, varscan2
- MAP3K3 | c.1215G>A p.E405= | Splice Region (SNP) | VAF 14/33 reads (42%) | catalogued as COSV51992435; called by muse, mutect2, varscan2
- MCPH1 | c.1441A>G p.I481V | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs768776312, COSV60917808; called by muse, mutect2, varscan2
- MEOX1 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV59356976; called by muse, mutect2, varscan2
- MUC6 | c.5670C>A p.H1890Q | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV70147339; called by muse, varscan2
- MYH15 | c.1133A>G p.Q378R | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV56316465; called by muse, mutect2, varscan2
- MYO18B | c.224C>G p.P75R | Missense Mutation (SNP) | VAF 67/251 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.571); catalogued as COSV59124824, COSV59143846; called by muse, mutect2, varscan2
- MYO3B | c.644C>A p.A215D | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV58712536; called by muse, mutect2, varscan2
- NBEAL2 | c.5264G>T p.R1755L | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV52761032, COSV52761630; called by muse, mutect2, varscan2
- NCAPG2 | c.3304A>G p.R1102G | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV51985266, COSV51990327; called by muse, mutect2, varscan2
- NCOA2 | c.321G>T p.Q107H | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV71764616; called by muse, mutect2, varscan2
- OR6Y1 | c.440G>C p.G147A | Missense Mutation (SNP) | VAF 77/85 reads (91%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as COSV56929141; called by muse, mutect2, varscan2
- ORC3 | c.1948G>C p.E650Q | Missense Mutation (SNP) | VAF 85/109 reads (78%) | SIFT tolerated (0.52); PolyPhen benign (0.213); catalogued as COSV57642564; called by muse, mutect2, varscan2
- PCDHB10 | c.1568C>A p.A523D | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as COSV53382170; called by muse, mutect2, varscan2
- PCLO | c.11281A>C p.K3761Q | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61656151; called by muse, mutect2, varscan2
- PCLO | c.6769G>T p.A2257S | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV61656156; called by muse, mutect2, varscan2
- PCLO | c.1986G>T p.K662N | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.295); catalogued as COSV61656163; called by muse, mutect2, varscan2
- PCSK2 | c.269A>G p.E90G | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV52739886; called by muse, mutect2, varscan2
- PDGFRA | c.3037A>G p.S1013G | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); catalogued as COSV57271709; called by muse, mutect2, varscan2
- PHRF1 | c.3679C>G p.H1227D (on ENST00000264555 / NM_001286581.2; = p.H1226D on NM_020901.4) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV52760254; called by muse, mutect2, varscan2
- PIWIL4 | c.606C>A p.C202* | Nonsense Mutation (SNP) | VAF 43/102 reads (42%) | catalogued as COSV54411396; called by muse, mutect2, varscan2
- PPM1H | c.1430G>T p.R477L | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV57377634, COSV57378235; called by muse, mutect2, varscan2
- PRB2 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV66982237, COSV66983928; called by muse, mutect2, varscan2
- PRSS58 | c.94G>T p.V32F | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV73488788; called by muse, mutect2, varscan2
- PTPRS | c.2786G>A p.R929H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as rs1313647555, COSV53615144; called by muse, mutect2
- PTPRZ1 | c.3502T>A p.L1168I | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.115); catalogued as COSV66442745; called by muse, mutect2, varscan2
- RAB3GAP2 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 162/193 reads (84%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.203); catalogued as COSV52966745; called by muse, mutect2, varscan2
- RAI1 | c.1231G>T p.A411S | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV55397066; called by muse, mutect2, varscan2
- RHPN1 | c.1097G>A p.G366D | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.214); catalogued as COSV56648659, COSV99073913; called by muse, mutect2, varscan2
- RNF135 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60434290; called by muse, mutect2, varscan2
- RYR1 | c.9080G>T p.S3027I | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV62106128; called by muse, mutect2, varscan2
- RYR1 | c.9081C>A p.S3027R | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV62106133; called by muse, mutect2, varscan2
- SETD2 | c.4588T>A p.S1530T | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.321); catalogued as COSV57446470; called by muse, mutect2
- SH3RF3 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1157040571, COSV58692162; called by muse, mutect2
- SLC2A11 | c.873G>T p.S291= (on ENST00000345044 / NM_001024938.4; = p.S298= on NM_030807.5) | Splice Region (SNP) | VAF 25/42 reads (60%) | catalogued as rs199527068, COSV55393313; called by muse, mutect2, varscan2
- SLC4A10 | c.756G>T p.M252I | Missense Mutation (SNP) | VAF 86/103 reads (83%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV55771551, COSV55792767; called by muse, mutect2, varscan2
- SLC4A8 | c.3001C>G p.L1001V | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV60656738; called by muse, mutect2
- SLC9A3 | c.2323C>A p.L775M | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV53803773; called by muse, mutect2, varscan2
- SPOCD1 | c.3412C>T p.H1138Y | Missense Mutation (SNP) | VAF 47/63 reads (75%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV57098774; called by muse, mutect2, varscan2
- TAS1R1 | c.1243C>T p.R415* | Nonsense Mutation (SNP) | VAF 31/43 reads (72%) | catalogued as rs772335281, COSV59839481; called by muse, mutect2, varscan2
- TBC1D16 | c.1510G>T p.G504W | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60480144; called by muse, mutect2, varscan2
- TG | c.1731C>A p.F577L | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55089061; called by muse, mutect2, varscan2
- TMPRSS15 | c.1996C>G p.L666V | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV53045717; called by muse, mutect2, varscan2
- TRPC7 | c.2207A>T p.K736M | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV61461653; called by muse, mutect2, varscan2
- TRPM3 | c.4231A>G p.M1411V (on ENST00000357533 / NM_001366142.2; = p.M1266V on NM_020952.6) | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.023); catalogued as COSV62592319; called by muse, mutect2, varscan2
- TTLL9 | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 22/89 reads (25%) | catalogued as COSV60595196; called by muse, mutect2, varscan2
- UBA1 | c.1697A>G p.Q566R | Missense Mutation (SNP) | VAF 67/95 reads (71%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as COSV60114679; called by muse, mutect2, varscan2
- UTS2R | c.1046C>A p.A349D | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as COSV57453587; called by mutect2, varscan2
- VCAN | c.2662T>A p.S888T | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.272); catalogued as COSV54113052; called by muse, mutect2, varscan2
- XPNPEP2 | c.1382A>T p.D461V | Missense Mutation (SNP) | VAF 45/52 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64369922; called by muse, mutect2, varscan2
- ZAN | c.4031C>G p.S1344C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as rs760035237, COSV61813323; called by muse, mutect2, varscan2
- ZNF135 | c.201G>T p.E67D | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV57884718; called by muse, mutect2, varscan2
- ZNF215 | c.623T>A p.L208Q | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV53494315; called by muse, mutect2, varscan2
- ZNF823 | c.326G>C p.G109A (on ENST00000341191 / NM_001297610.2; = p.G65A on NM_017507.2) | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.769); catalogued as COSV57875346; called by muse, mutect2, varscan2
- ZNF85 | c.824C>A p.T275N | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.02); catalogued as COSV60216509; called by muse, mutect2, varscan2
- ZNF98 | c.622A>G p.K208E | Missense Mutation (SNP) | VAF 138/279 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV63338639; called by muse, mutect2, varscan2
- CALB1 | c.73del p.A25Lfs*15 | Frame Shift Del (DEL) | VAF 49/154 reads (32%) | called by mutect2, pindel, varscan2
- GFI1B | c.618C>A p.S206R | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- HECW1 | c.3753-5_3756delinsTT p.X1251_splice | Splice Site (DEL) | VAF 15/61 reads (25%) | called by pindel, varscan2*
- NOL4 | c.1474_1480del p.I492Lfs*68 | Frame Shift Del (DEL) | VAF 36/101 reads (36%) | called by mutect2, pindel, varscan2
- PCDHB16 | c.596dup p.L200Afs*32 | Frame Shift Ins (INS) | VAF 23/74 reads (31%) | called by mutect2, pindel, varscan2
- PCK1 | c.1779_1780del p.K594Vfs*13 | Frame Shift Del (DEL) | VAF 55/154 reads (36%) | called by pindel, varscan2
- RB1 | c.2275_2307del p.V759_L769del | In Frame Del (DEL) | VAF 41/78 reads (53%) | called by mutect2, pindel, varscan2
- ADGRB1 | c.3753C>T p.G1251= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV60101761; called by muse, mutect2, varscan2
- BPIFA2 | c.735G>T p.L245= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as COSV53612266; called by muse, mutect2, varscan2
- CDK2 | c.882C>G p.P294= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV57187179; called by muse, mutect2, varscan2
- CST9L | c.258A>G p.V86= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as COSV65408165; called by muse, mutect2, varscan2
- DPP3 | c.864C>A p.G288= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs781635422, COSV64757586; called by muse, mutect2, varscan2
- EPHB3 | c.1432C>A p.R478= | Silent (SNP) | VAF 183/346 reads (53%) | catalogued as COSV57807641, COSV57808210; called by muse, mutect2, varscan2
- GNAS | c.378G>T p.G126= | Silent (SNP) | VAF 25/42 reads (60%) | catalogued as COSV58342805; called by muse, mutect2, varscan2
- MAMDC2 | c.162T>C p.Y54= | Silent (SNP) | VAF 28/55 reads (51%) | catalogued as rs1230973796, COSV65859813; called by muse, mutect2, varscan2
- MYLIP | c.1005T>A p.V335= | Silent (SNP) | VAF 93/201 reads (46%) | catalogued as COSV62767394; called by muse, mutect2, varscan2
- PCDHA3 | c.138C>A p.G46= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV65369936; called by muse, mutect2, varscan2
- PCDHA8 | c.2034G>A p.A678= | Silent (SNP) | VAF 52/88 reads (59%) | catalogued as COSV65326549; called by muse, mutect2, varscan2
- PRODH2 | c.1026G>T p.G342= (on ENST00000301175; = p.G266= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV56561266; called by muse, mutect2, varscan2
- PTPN5 | c.1203C>A p.I401= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV62127765; called by muse, mutect2, varscan2
- RUSC1 | c.606G>A p.R202= | Silent (SNP) | VAF 284/331 reads (86%) | catalogued as COSV52741761; called by muse, mutect2, varscan2
- RYR3 | c.4698C>T p.S1566= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs563422149, COSV66803441; ClinVar: uncertain significance; called by mutect2, varscan2
- SERPINF2 | c.1420T>C p.L474= | Silent (SNP) | VAF 33/43 reads (77%) | catalogued as COSV60665271; called by muse, mutect2, varscan2
- SIGLEC15 | c.555G>T p.A185= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV67181368, COSV67181599; called by muse, mutect2, varscan2
- SLC29A1 | c.756C>T p.L252= | Silent (SNP) | VAF 50/88 reads (57%) | catalogued as rs755679281, COSV57579844; called by muse, mutect2, varscan2
- SLC35A5 | c.1068C>T p.S356= | Silent (SNP) | VAF 40/126 reads (32%) | catalogued as rs1217218625, COSV53727156; called by muse, mutect2, varscan2
- SLC6A3 | c.1503T>A p.V501= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV54367880; called by muse, mutect2, varscan2
- SORCS2 | c.1815G>T p.S605= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV61179581; called by muse, mutect2, varscan2
- SPATA46 | c.606C>A p.I202= | Silent (SNP) | VAF 40/116 reads (34%) | catalogued as COSV62638520; called by muse, mutect2, varscan2
- TBX5 | c.669G>T p.T223= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs376519728, COSV59863244; called by muse, mutect2, varscan2
- TRAPPC10 | c.2272C>T p.L758= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV52380200; called by muse, mutect2, varscan2
- TSC22D2 | c.615C>T p.S205= | Silent (SNP) | VAF 25/108 reads (23%) | catalogued as COSV62623189; called by muse, mutect2, varscan2
- WDR49 | c.618G>A p.R206= (on ENST00000308378 / NM_001366158.1; = p.R547= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 33/129 reads (26%) | catalogued as rs982125054, COSV57714609; called by muse, mutect2, varscan2
- WDR76 | c.1644G>T p.L548= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as COSV55478835; called by muse, mutect2, varscan2
- XAGE2 | c.327A>T p.S109= | Silent (SNP) | VAF 154/203 reads (76%) | called by muse, mutect2, varscan2
- ZFYVE28 | c.2451C>T p.D817= | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as rs146945400, COSV52119117; called by muse, mutect2, varscan2
- ZNF830 | c.30G>T p.P10= | Silent (SNP) | VAF 49/113 reads (43%) | catalogued as COSV58490951; called by muse, mutect2, varscan2
- ZNF99 | c.1104C>T p.P368= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV101233907, COSV68056170; called by muse, mutect2, varscan2
- SSPOP | n.14817A>G | RNA (SNP) | VAF 9/18 reads (50%) | catalogued as COSV65134813; called by muse, mutect2, varscan2
